Somatic mutation profile of tumor specimen 0DPQQO from CCDI case PBCDZR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.3 years (4,145 days).
Specimen 0DPQQO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 938a4298-c9ab-411f-b094-c59d3ee4dee2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPQQD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a325751c-e883-496f-8b55-4a29df3b8720

The open-access MAF lists 16 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, Intron 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DGKK | c.2741G>T p.R914L | Missense Mutation (SNP) | VAF 47/320 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65706128; called by muse, mutect2, varscan2
- GPAM | c.1555C>T p.R519C | Missense Mutation (SNP) | VAF 79/420 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs535134703, COSV62081176; called by muse, mutect2, varscan2
- NKX2-3 | c.875G>A p.G292D | Missense Mutation (SNP) | VAF 66/130 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.154); catalogued as COSV60728842; called by muse, varscan2
- PREPL | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 48/252 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748348034; called by muse, mutect2, varscan2
- SRGAP3 | c.2824G>A p.G942S | Missense Mutation (SNP) | VAF 95/407 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371641995, COSV99062240; called by muse, mutect2, varscan2
- KIF5B | c.645G>C p.E215D | Missense Mutation (SNP) | VAF 28/389 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.904); called by muse, mutect2
- KRT85 | c.837G>C p.K279N | Missense Mutation (SNP) | VAF 81/391 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- PLB1 | c.4234G>T p.A1412S | Missense Mutation (SNP) | VAF 118/480 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYP4F8 | c.1194C>T p.F398= | Silent (SNP) | VAF 90/354 reads (25%) | catalogued as rs61748806, COSV57855331; called by muse, mutect2, varscan2
- SETD1B | c.1908C>T p.G636= | Silent (SNP) | VAF 48/385 reads (12%) | catalogued as rs753493280; called by muse, mutect2, varscan2
- STXBP5 | c.1176G>A p.L392= | Silent (SNP) | VAF 51/216 reads (24%) | called by muse, mutect2, varscan2
- TPM2 | c.537G>A p.S179= | Silent (SNP) | VAF 51/306 reads (17%) | catalogued as rs758819415; called by muse, mutect2, varscan2
- ADARB2 | c.-21C>A | 5'UTR (SNP) | VAF 15/192 reads (8%) | catalogued as rs1041922595; called by muse, mutect2
- CERKL | c.1211+73C>A | Intron (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- SLC12A3 | c.-25C>T | 5'UTR (SNP) | VAF 15/107 reads (14%) | catalogued as COSV99343978; called by muse, mutect2, varscan2
- SLC18A2 | c.1186+37G>A | Intron (SNP) | VAF 27/398 reads (7%) | catalogued as rs750376036, COSV53694170; called by muse, mutect2
